Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACR8, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACR8-TTP1-A (Primary Tumor).

[page 1 of 2]
Material to be examined and removal site:

1. Left lung
2. Lymph node subcarinal
3. Lymph node under aortic or of the botallo's duct
4. Lymph node para esophageal
5. Lymph node peri arterial
6. Parietal pleura

CDDP-YP-ACR8-01-PR

Macroscopic report:

1. In the same container there are a lung weight gr 1415 and measuring cm 20x21x5, separate from which it identifies main bronchus with extensive lymphatic structures. It is present in the pulmonary hilar extensively necrotic lesion of diameter cm 7, mainly extended to the upper lobe but also an interesting interlobar fissure.
2. Reddish white multiple fragments, the greatest of maximum diameter cm 3. To the cuts present markedly hemorrhagic aspect.
3. Reddish white multiple fragments, , the greatest of maximum diameter cm 3. To the cuts present hemorrhagic aspect.
4. Reddish white multiple fragments, the greatest of maximum diameter cm 4.5. To the cuts present markedly hemorrhagic aspect.
5. Nodule brownish red of maximum diameter cm 5. To the cuts presents nodular area blackish white of maximum diameter cm 3.
6. Fragments of tissue referable to pleura of cm 7x3 with brownish area of increased consistence.

Histopathological diagnosis

1. Poorly differentiated lung adenocarcinoma G3 of the upper lobe with areas of necrosis and infiltrating the beneath pleural connective tissue and interlobar fissure, four hilar lymph nodes of the upper lobe free; massive metastases to a package of hilar lymph nodes.
2. Massive nodal metastases a 2 lymph node of 2.
3. Four lymph node free.
4. Massive nodal metastases a 4 lymph node of 4.
5. Massive nodal metastases a 2 lymph node of 2.
6. Parietal pleura free of cancer.

pT2 N1 Mx

Codes SNOMED

T-28500 M-81403
T-C4300 M-80006

ICD-0-3

adenocarcinoma, NOS 8140/3

Site

Ⓔ lung, upper lobe C34.1

ICD-10

C34.12

fw
10/13/16

[page 2 of 2]
Cytological diagnosis

It is observed the presence of:

It is observed the presence of malignant tumor cells.

Description compatible with large-cell malignancy

Codes SNOMED

T-26000 M-80123

Material to be examined and removal site:

Lung: left upper lobar bronchus

Macroscopic report:

White brownish multiple fragments of diameter between cm 0.1 and 0.3.

Histopathological diagnosis:

Neoplasia of large poorly differentiated cells (probable adenocarcinoma), fragments.

Codes SNOMED

T-26000 M-80003 M-81403

Source: NCI Genomic Data Commons file 0139c0eb-8b47-4a5e-8612-b4af6211d56a (CDDP-ACR8-TTP1.7168CBB9-597D-470B-BCB0-821AE3C7B591.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).